Somatic mutation profile of tumor specimen TARGET-30-PATFXV-01A (aliquot TARGET-30-PATFXV-01A-01D) from TARGET case TARGET-30-PATFXV, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (648 days).
Specimen TARGET-30-PATFXV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a085139-06e1-444c-8da0-750173d2da75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATFXV-10A (Blood Derived Normal), aliquot TARGET-30-PATFXV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7eda3ab-7027-489f-b4e9-e5fc04f5666a

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRG4 | c.3257G>T p.R1086L | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs755135197, COSV54950521, COSV54963624; called by muse, mutect2, varscan2
- CACNA1F | c.4414G>T p.G1472W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59906314; called by muse, mutect2, varscan2
- CIDEC | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.123); catalogued as COSV61062309; called by muse, mutect2, varscan2
- DOCK3 | c.1227G>T p.L409F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs765326812, COSV56540619; called by muse, mutect2, varscan2
- FAM135B | c.2101C>G p.R701G | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV52744808; called by muse, mutect2, varscan2
- GPR158 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66278408; called by muse, mutect2, varscan2
- IFIT1B | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV65663648; called by muse, mutect2, varscan2
- KRTAP4-4 | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs774112833, COSV66811457; called by muse, mutect2, varscan2
- MYBL1 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV72919144; called by muse, mutect2, varscan2
- OVGP1 | c.1717A>T p.K573* | Nonsense Mutation (SNP) | VAF 66/135 reads (49%) | catalogued as COSV63859668; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.176C>A p.P59Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57964381, COSV57967487; called by muse, mutect2, varscan2
- PPFIA4 | c.1463G>A p.R488H (on ENST00000447715; = p.R463H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs907804074, COSV55314996; called by muse, mutect2
- SNX29 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs780253205, COSV60050591; called by muse, mutect2, varscan2
- UIMC1 | c.2106G>T p.Q702H | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as rs1561696092, COSV65894665; called by muse, mutect2, varscan2
- ACSBG2 | c.1578C>A p.P526= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV53126865, COSV99397621; called by muse, mutect2, varscan2
- MAGEE1 | c.1143G>T p.P381= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV63911294, COSV63911635; called by muse, mutect2, varscan2
- PTRHD1 | c.141G>T p.L47= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV53231756, COSV53231779; called by muse, mutect2, varscan2
- SMG8 | c.1686C>T p.G562= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV56286513; called by muse, mutect2, varscan2
- ST14 | c.1170C>T p.P390= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs148170078; called by muse, mutect2, varscan2
- OR2U1P | n.732T>A | RNA (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
